Somatic mutation profile of tumor specimen MMRF_2314_1_BM_CD138pos (aliquot MMRF_2314_1_BM_CD138pos_T1_KHS5U_L11052) from MMRF case MMRF_2314, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 59.6 years (21,777 days).
Specimen MMRF_2314_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 449702a1-1b7d-4040-9bb5-36c2472c5f4b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2314_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2314_1_PB_WBC_C2_KHS5U_L11051; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0aac0cd3-9490-4dd2-aadd-38ab80919d9b

The open-access MAF lists 133 somatic variants for this specimen: 52 protein-altering or splice-affecting, 19 silent, 62 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, 3'UTR 33, Silent 19, Intron 15, 5'UTR 5, 3'Flank 4, RNA 4, In Frame Del 3, Nonsense Mutation 2, Splice Site 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 49/59 reads (83%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SETD2 | c.4715+1G>T p.X1572_splice | Splice Site (SNP) | VAF 71/148 reads (48%) | hotspot (GDC flag); catalogued as COSV57431126, COSV57439397; called by muse, mutect2, varscan2
- ANKRD18A | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 89/292 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV68803601, COSV68803607; called by muse, mutect2, varscan2
- ASB1 | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 112/203 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs763966170; called by muse, mutect2, varscan2
- BPHL | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.047); catalogued as rs1358656093; called by muse, mutect2
- C4orf50 | c.163G>A p.A55T (on ENST00000324058; = p.A1287T on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1314051605; called by muse, mutect2, varscan2
- CYP7B1 | c.389A>G p.K130R | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.038); catalogued as COSV59585766, COSV59594603; called by muse, mutect2, varscan2
- DNA2 | c.2872A>G p.I958V | Missense Mutation (SNP) | VAF 75/153 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs575412271; called by muse, mutect2, varscan2
- DNAJB5 | c.247_255del p.S83_S85del | In Frame Del (DEL) | VAF 64/214 reads (30%) | catalogued as rs774096148; called by mutect2, varscan2
- IGHV2-70 | c.105G>C p.Q35H | Missense Mutation (SNP) | VAF 39/41 reads (95%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); catalogued as rs559969703; called by muse, mutect2, varscan2
- IGKV4-1 | c.259C>T p.R87* | Nonsense Mutation (SNP) | VAF 59/64 reads (92%) | catalogued as rs376415297; called by muse, mutect2, varscan2
- IGLV3-1 | c.290A>G p.Q97R | Missense Mutation (SNP) | VAF 57/219 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.11); catalogued as rs372648481; called by muse, varscan2
- IGSF9B | c.2669G>A p.R890H | Missense Mutation (SNP) | VAF 100/243 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.382); catalogued as rs761729959, COSV58069518, COSV58073730; called by muse, mutect2, varscan2
- ITGBL1 | c.886T>C p.C296R | Missense Mutation (SNP) | VAF 116/240 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66011973; called by muse, mutect2, varscan2
- LAMA4 | c.428C>A p.A143E | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57902848; called by muse, mutect2, varscan2
- NDUFAF3 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138275059; called by muse, mutect2, varscan2
- NRTN | c.179T>C p.L60P | Missense Mutation (SNP) | VAF 209/329 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs758472903; called by muse, varscan2
- OR6K2 | c.943G>A p.V315I | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs141972386, COSV62743235; called by muse, mutect2, varscan2
- USH2A | c.8264T>C p.L2755P | Missense Mutation (SNP) | VAF 78/171 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV56368478; called by muse, mutect2, varscan2
- ADAMTS12 | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 49/154 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ANKRD31 | c.3329A>T p.N1110I | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- AP2B1 | c.2614_2616del p.N872del | In Frame Del (DEL) | VAF 29/56 reads (52%) | called by mutect2, pindel, varscan2
- ARSJ | c.431T>G p.I144S | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- ATG16L2 | c.1366+8C>A | Splice Region (SNP) | VAF 18/60 reads (30%) | called by muse, mutect2, varscan2
- ATP10B | c.1736C>A p.S579Y | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (1); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- CCNB3 | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 28/30 reads (93%) | SIFT tolerated (0.15); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CD22 | c.1707C>G p.Y569* | Nonsense Mutation (SNP) | VAF 58/194 reads (30%) | called by muse, mutect2, varscan2
- EVC | c.1934C>T p.A645V | Missense Mutation (SNP) | VAF 63/128 reads (49%) | SIFT tolerated (0.9); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- FLRT2 | c.1147C>A p.P383T | Missense Mutation (SNP) | VAF 138/286 reads (48%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, varscan2
- GHSR | c.521G>T p.S174I | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- GRIA2 | c.8del p.K3Rfs*16 | Frame Shift Del (DEL) | VAF 101/300 reads (34%) | called by mutect2, pindel, varscan2
- HABP2 | c.802T>C p.W268R | Missense Mutation (SNP) | VAF 83/171 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGF2 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 94/297 reads (32%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGHG1 | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- MUC22 | c.3149C>A p.A1050E | Missense Mutation (SNP) | VAF 184/425 reads (43%) | SIFT tolerated (0.92); called by muse, mutect2, varscan2
- NOBOX | c.1183C>T p.P395S | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- NOTCH3 | c.2930G>A p.C977Y | Missense Mutation (SNP) | VAF 61/172 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NYAP2 | c.982A>C p.N328H | Missense Mutation (SNP) | VAF 57/132 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDHGA2 | c.199G>A p.V67I | Missense Mutation (SNP) | VAF 128/417 reads (31%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- PLBD1 | c.92C>T p.T31I | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- PPP1CC | c.656dup p.N219Kfs*2 | Frame Shift Ins (INS) | VAF 138/323 reads (43%) | called by mutect2, pindel, varscan2
- PREX2 | c.283T>G p.L95V | Missense Mutation (SNP) | VAF 173/328 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.402); called by muse, mutect2, varscan2
- RAD50 | c.584T>A p.V195E | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- RAPGEF2 | c.1629T>A p.S543R | Missense Mutation (SNP) | VAF 136/300 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.097); called by muse, varscan2
- RDH14 | c.211_216del p.I71_M72del | In Frame Del (DEL) | VAF 9/22 reads (41%) | called by mutect2, pindel, varscan2
- RGS22 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- RIMS1 | c.293T>C p.I98T | Missense Mutation (SNP) | VAF 79/158 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SLC22A10 | c.214C>A p.L72I | Missense Mutation (SNP) | VAF 145/505 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- SPEG | c.4730C>T p.A1577V | Missense Mutation (SNP) | VAF 77/153 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- TENT5C | c.938T>C p.V313A | Missense Mutation (SNP) | VAF 79/90 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- WDR87 | c.3898G>C p.V1300L | Missense Mutation (SNP) | VAF 80/289 reads (28%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- ZNF804A | c.260T>G p.L87R | Missense Mutation (SNP) | VAF 56/109 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AATK | c.1695C>T p.D565= (on ENST00000326724 / NM_001080395.3; = p.D462= on NM_004920.2) | Silent (SNP) | VAF 21/44 reads (48%) | catalogued as rs1377659658; called by muse, mutect2, varscan2
- ABCA3 | c.517C>T p.L173= | Silent (SNP) | VAF 53/112 reads (47%) | catalogued as COSV100069096; called by muse, mutect2, varscan2
- ADH7 | c.579C>T p.G193= | Silent (SNP) | VAF 67/162 reads (41%) | catalogued as rs371551288; called by muse, mutect2, varscan2
- AFF3 | c.1812G>A p.R604= | Silent (SNP) | VAF 15/25 reads (60%) | catalogued as rs1375466233; called by muse, mutect2, varscan2
- AP002512.3 | c.15C>T p.T5= | Silent (SNP) | VAF 85/125 reads (68%) | catalogued as rs559337190, COSV56566892; called by muse, mutect2, varscan2
- ATP10B | c.1737C>A p.S579= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as COSV59154682; called by muse, mutect2, varscan2
- CCNB1 | c.258A>T p.V86= | Silent (SNP) | VAF 110/172 reads (64%) | called by muse, mutect2, varscan2
- CSNK1E | c.1074G>A p.P358= | Silent (SNP) | VAF 32/56 reads (57%) | catalogued as rs749101630; called by muse, mutect2, varscan2
- EN2 | c.588C>T p.D196= | Silent (SNP) | VAF 48/94 reads (51%) | called by muse, mutect2, varscan2
- FAM170B | c.135G>A p.S45= | Silent (SNP) | VAF 44/107 reads (41%) | called by muse, mutect2, varscan2
- HTRA1 | c.522C>T p.D174= | Silent (SNP) | VAF 56/117 reads (48%) | catalogued as rs564184534, COSV64565518; called by muse, mutect2, varscan2
- KCTD15 | c.549C>T p.L183= | Silent (SNP) | VAF 37/184 reads (20%) | catalogued as rs770801302; called by muse, mutect2, varscan2
- LRRC4B | c.453G>A p.T151= | Silent (SNP) | VAF 110/338 reads (33%) | catalogued as rs1568715320; called by muse, mutect2, varscan2
- NTRK3 | c.1557G>A p.Q519= | Silent (SNP) | VAF 76/214 reads (36%) | catalogued as COSV58114692; called by muse, mutect2, varscan2
- PTGFRN | c.1311G>A p.G437= | Silent (SNP) | VAF 72/78 reads (92%) | catalogued as rs1295477028; called by muse, mutect2, varscan2
- RIPOR3 | c.465C>A p.G155= | Silent (SNP) | VAF 11/99 reads (11%) | catalogued as COSV50387628; called by muse, mutect2, varscan2
- SYNE1 | c.2475G>A p.T825= (on ENST00000367255 / NM_182961.4; = p.T832= on NM_033071.3) | Silent (SNP) | VAF 38/42 reads (90%) | catalogued as rs758181903, COSV55088084; called by muse, mutect2, varscan2
- TTN | c.71148T>C p.R23716= (on ENST00000591111; = p.R16292= on NM_003319.4) | Silent (SNP) | VAF 133/309 reads (43%) | catalogued as rs1474978344; called by muse, mutect2, varscan2
- XDH | c.2238G>A p.E746= | Silent (SNP) | VAF 46/94 reads (49%) | catalogued as rs763651302; called by muse, mutect2, varscan2
- ABCF2 | c.*586C>T | 3'UTR (SNP) | VAF 56/107 reads (52%) | called by muse, mutect2, varscan2
- AC006486.1 | c.23-3080C>T | Intron (SNP) | VAF 56/89 reads (63%) | called by muse, mutect2, varscan2
- ACTG1 | c.-23C>T | 5'UTR (SNP) | VAF 127/289 reads (44%) | catalogued as rs781887460, COSV59509534; called by muse, mutect2, varscan2
- ALG10B | c.-100C>A | 5'UTR (SNP) | VAF 50/99 reads (51%) | called by muse, mutect2, varscan2
- ANKRD62P1 | n.276A>G | RNA (SNP) | VAF 64/125 reads (51%) | called by muse, mutect2, varscan2
- ARL10 | c.*6164G>A | 3'UTR (SNP) | VAF 25/39 reads (64%) | called by muse, mutect2
- ARPP19P1 | n.56A>G | RNA (SNP) | VAF 47/90 reads (52%) | called by muse, mutect2, varscan2
- ATF2 | c.627-194del | Intron (DEL) | VAF 12/35 reads (34%) | called by mutect2, pindel, varscan2
- ATG13 | c.*1645C>T | 3'UTR (SNP) | VAF 56/181 reads (31%) | called by muse, mutect2, varscan2
- B9D2 | c.*2G>A | 3'UTR (SNP) | VAF 52/147 reads (35%) | called by muse, mutect2
- BCL6 | chr3:187722267 del G | 3'Flank (DEL) | VAF 8/27 reads (30%) | called by mutect2, pindel
- BMP1 | c.731-196G>T | Intron (SNP) | VAF 125/299 reads (42%) | called by muse, mutect2, varscan2
- BRD2 | c.-665A>G | 5'UTR (SNP) | VAF 71/169 reads (42%) | catalogued as rs1288722787; called by muse, mutect2, varscan2
- BTG1 | c.*679C>T | 3'UTR (SNP) | VAF 12/36 reads (33%) | called by muse, mutect2, varscan2
- BTG1 | c.*449C>A | 3'UTR (SNP) | VAF 9/28 reads (32%) | called by muse, mutect2, varscan2
- CFL2 | c.*928T>A | 3'UTR (SNP) | VAF 57/130 reads (44%) | called by muse, mutect2, varscan2
- COLQ | c.*583G>A | 3'UTR (SNP) | VAF 69/149 reads (46%) | catalogued as rs747056584; called by muse, mutect2, varscan2
- CREB1 | c.*4049C>T | 3'UTR (SNP) | VAF 37/65 reads (57%) | called by muse, mutect2, varscan2
- CRISPLD1 | c.*32T>G | 3'UTR (SNP) | VAF 78/170 reads (46%) | called by muse, mutect2, varscan2
- CST2 | c.*116G>A | 3'UTR (SNP) | VAF 64/136 reads (47%) | called by muse, mutect2, varscan2
- DLGAP4 | c.*688C>G | 3'UTR (SNP) | VAF 58/125 reads (46%) | called by muse, mutect2, varscan2
- DTL | c.*8_*20del | 3'UTR (DEL) | VAF 62/203 reads (31%) | called by mutect2, pindel, varscan2
- EGLN3 | c.357+2067del | Intron (DEL) | VAF 40/102 reads (39%) | called by mutect2, varscan2
- ESR2 | c.1407-280T>C | Intron (SNP) | VAF 46/94 reads (49%) | called by muse, mutect2, varscan2
- EVA1A | c.*30G>A | 3'UTR (SNP) | VAF 15/24 reads (63%) | called by muse, mutect2, varscan2
- FAM32EP | chr12:126458053 G>T | 3'Flank (SNP) | VAF 38/74 reads (51%) | called by muse, mutect2, varscan2
- FCRL1 | c.52+159G>T | Intron (SNP) | VAF 7/13 reads (54%) | called by muse, mutect2, varscan2
- FEM1A | c.*27C>T | 3'UTR (SNP) | VAF 28/84 reads (33%) | catalogued as rs1446138128; called by muse, mutect2, varscan2
- GLCCI1 | c.*420A>C | 3'UTR (SNP) | VAF 22/54 reads (41%) | catalogued as COSV99780783; called by muse, mutect2, varscan2
- HLA-DOB | c.643+39G>A | Intron (SNP) | VAF 15/33 reads (45%) | called by muse, mutect2
- HOATZ | c.453-457C>A | Intron (SNP) | VAF 32/121 reads (26%) | called by muse, mutect2, varscan2
- KCTD15 | c.*566G>C | 3'UTR (SNP) | VAF 3/22 reads (14%) | catalogued as rs1168419620; called by muse, mutect2
- LINC01565 | n.1530A>G | RNA (SNP) | VAF 30/66 reads (45%) | called by muse, mutect2, varscan2
- LPP | c.*6088A>G | 3'UTR (SNP) | VAF 47/116 reads (41%) | called by muse, mutect2, varscan2
- MBD5 | c.*2392A>G | 3'UTR (SNP) | VAF 24/57 reads (42%) | catalogued as rs1021111772; called by muse, mutect2, varscan2
- MBNL1 | c.174+39616C>G | Intron (SNP) | VAF 35/84 reads (42%) | called by muse, mutect2, varscan2
- MED22 | c.414-192C>G | Intron (SNP) | VAF 69/215 reads (32%) | catalogued as rs1291762774; called by muse, mutect2, varscan2
- MMAA | chr4:145658017 T>A | 3'Flank (SNP) | VAF 15/30 reads (50%) | called by muse, mutect2, varscan2
- MMAB | c.*689A>C | 3'UTR (SNP) | VAF 111/227 reads (49%) | called by muse, mutect2, varscan2
- MTFR1 | c.*1198G>A | 3'UTR (SNP) | VAF 29/58 reads (50%) | called by muse, mutect2, varscan2
- NFE2L2 | chr2:177227613 del TCAG | 3'Flank (DEL) | VAF 8/23 reads (35%) | called by mutect2, pindel, varscan2
- NKX6-3 | c.*1248A>G | 3'UTR (SNP) | VAF 22/51 reads (43%) | called by muse, mutect2, varscan2
- NPFF | c.103-103G>A | Intron (SNP) | VAF 49/116 reads (42%) | catalogued as rs775183605; called by muse, mutect2, varscan2
- PCGF5 | c.*2329A>G | 3'UTR (SNP) | VAF 37/67 reads (55%) | catalogued as rs944187521; called by muse, mutect2, varscan2
- PCGF5 | c.*4221A>G | 3'UTR (SNP) | VAF 24/53 reads (45%) | called by muse, mutect2, varscan2
- PI15 | c.*2441G>A | 3'UTR (SNP) | VAF 17/45 reads (38%) | called by muse, mutect2, varscan2
- PLA2G6 | c.209+1306T>G | Intron (SNP) | VAF 63/161 reads (39%) | called by muse, mutect2, varscan2
- PRORY | n.471G>A | RNA (SNP) | VAF 40/42 reads (95%) | catalogued as rs1164427181; called by muse, mutect2, varscan2
- RAB10 | c.-4C>A | 5'UTR (SNP) | VAF 13/41 reads (32%) | catalogued as COSV99266098; called by muse, mutect2, varscan2
- RAB41 | chrX:70282101 G>A | 5'Flank (SNP) | VAF 11/12 reads (92%) | called by muse, mutect2, varscan2
- RIN3 | c.2632-810G>A | Intron (SNP) | VAF 42/86 reads (49%) | called by muse, mutect2, varscan2
- SCN9A | c.*1254G>T | 3'UTR (SNP) | VAF 46/115 reads (40%) | called by muse, mutect2, varscan2
- SERTAD4 | c.*2058A>T | 3'UTR (SNP) | VAF 39/85 reads (46%) | called by muse, mutect2, varscan2
- SRFBP1 | c.*184G>A | 3'UTR (SNP) | VAF 25/68 reads (37%) | called by muse, mutect2, varscan2
- SYN1 | c.*407T>C | 3'UTR (SNP) | VAF 56/60 reads (93%) | called by muse, mutect2, varscan2
- TMEM44 | c.612+32T>A | Intron (SNP) | VAF 32/71 reads (45%) | called by muse, mutect2, varscan2
- TYW5 | c.234-139A>G | Intron (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2, varscan2
- USP37 | c.*4643_*4646del | 3'UTR (DEL) | VAF 28/53 reads (53%) | called by mutect2, pindel, varscan2
- WDR3 | c.*356G>T | 3'UTR (SNP) | VAF 18/21 reads (86%) | called by muse, mutect2, varscan2
- ZFYVE26 | c.*1751C>T | 3'UTR (SNP) | VAF 20/44 reads (45%) | called by muse, mutect2, varscan2
- ZNF415 | c.-145C>A | 5'UTR (SNP) | VAF 29/102 reads (28%) | called by muse, mutect2, varscan2
- ZNF662 | c.*3854C>T | 3'UTR (SNP) | VAF 41/121 reads (34%) | catalogued as rs975331064; called by muse, mutect2, varscan2
